Somatic mutation profile of tumor specimen HCM-CSHL-0241-C18-01A (aliquot HCM-CSHL-0241-C18-01A-21D-A82H-36) from HCMI case HCM-CSHL-0241-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-CSHL-0241-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbd6eb36-d5c4-412b-aa94-b12eb707b72e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0241-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0241-C18-11A-11D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/127f6bcb-1f89-4664-8a53-332c69bd69da

The open-access MAF lists 174 somatic variants for this specimen: 124 protein-altering or splice-affecting, 49 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 49, Nonsense Mutation 7, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 241/775 reads (31%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 230/488 reads (47%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 49/225 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 122/401 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 118/686 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.156); catalogued as rs778285678; called by muse, mutect2, varscan2
- ANKRD17 | c.7057G>A p.G2353R | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.159); catalogued as rs139173196; called by muse, mutect2, varscan2
- ARHGAP22 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 117/574 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1003561932; called by muse, mutect2, varscan2
- ASB2 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 26/736 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1246944321; called by muse, mutect2
- ATP8B2 | c.536C>T p.A179V (on ENST00000672630; = p.A146V on NM_001005855.2) | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs776939812, COSV59245184; called by muse, varscan2
- C3orf22 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 114/478 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs762729878, COSV59072815; called by muse, mutect2, varscan2
- CASS4 | c.1687G>T p.V563F | Missense Mutation (SNP) | VAF 65/441 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64387689; called by muse, mutect2, varscan2
- CBLIF | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs150639344; called by muse, mutect2, varscan2
- CHSY3 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768317088, COSV100519385, COSV100519570; called by muse, mutect2, varscan2
- CLEC4G | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs1294612150, COSV61003413; called by muse, mutect2, varscan2
- CNNM4 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 50/551 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs769185337, COSV65660393, COSV65661394; called by muse, mutect2
- CORO7-PAM16 | c.2881C>T p.R961* | Nonsense Mutation (SNP) | VAF 213/525 reads (41%) | catalogued as rs1314983113; called by muse, mutect2, varscan2
- CSMD2 | c.9785C>T p.P3262L | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1305136343; called by muse, mutect2, varscan2
- DNAH11 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs763926220, COSV100178444; called by muse, varscan2
- DRD3 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 65/296 reads (22%) | catalogued as rs201369546, COSV55678948; called by muse, mutect2, varscan2
- DYNC1I1 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV61472776; called by muse, mutect2, varscan2
- EPB41L3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 141/446 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1352407489; called by muse, mutect2, varscan2
- FAM236C | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1364780861; called by muse, mutect2
- FAM47A | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 59/758 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.546); catalogued as COSV60497114; called by muse, mutect2
- FERD3L | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV51762036; called by muse, mutect2, varscan2
- FGF3 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 32/785 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs781935233, COSV61925597; called by muse, mutect2
- FUBP1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1233786882; called by muse, mutect2, varscan2
- GOLGA3 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs374651529; called by muse, mutect2, varscan2
- GSG1L | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 23/369 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1174353861, COSV66585933; called by muse, mutect2
- HCN4 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205804, COSV56081300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HJV | c.466C>T p.R156W (on ENST00000336751 / NM_213653.4; = p.R43W on NM_145277.5) | Missense Mutation (SNP) | VAF 158/582 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as rs1553769683, COSV60951694, COSV60953059; called by muse, mutect2, varscan2
- IBSP | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1021445456; called by muse, mutect2, varscan2
- ISM2 | c.930G>T p.W310C | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV53635462; called by muse, mutect2, varscan2
- KY | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs765639887; called by muse, mutect2, varscan2
- LMBRD1 | c.868G>A p.A290T (on ENST00000649011; = p.A268T on NM_018368.4) | Missense Mutation (SNP) | VAF 101/315 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs143758103, COSV65299886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LOXL2 | c.1638C>T p.T546= | Splice Region (SNP) | VAF 31/329 reads (9%) | catalogued as rs746018634; called by muse, mutect2
- MAP2K4 | c.1046C>G p.T349R | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.136); catalogued as COSV62255136; called by muse, mutect2, varscan2
- MAP3K13 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 89/407 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs779925776; called by muse, mutect2, varscan2
- MUC16 | c.38320C>T p.R12774C | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1380157121; called by muse, mutect2, varscan2
- MYO15A | c.5767C>T p.R1923C | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs753471215, COSV52765554, COSV99232249; called by muse, mutect2
- NAALAD2 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs749818857, COSV58961384; called by muse, mutect2, varscan2
- NGF | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as rs750829893, COSV65688827; called by muse, mutect2
- NLGN4X | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 84/469 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); catalogued as rs373602022, COSV52014407; called by muse, mutect2, varscan2
- NLRP4 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 119/413 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56709059; called by muse, mutect2, varscan2
- OR2T1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 23/428 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as rs368518017; called by muse, mutect2
- OR52N4 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 45/442 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs753229074; called by muse, mutect2, varscan2
- PCDHA7 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 20/622 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs782034445, COSV65342515; called by muse, mutect2
- PDE5A | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142619828; called by muse, mutect2, varscan2
- PLA2G5 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 43/354 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs387906796, CM1110072, COSV100908282, COSV64282789; ClinVar: affects; called by muse, mutect2, varscan2
- PLD1 | c.1038C>G p.I346M | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as COSV100577809; called by muse, mutect2
- PPP1R3A | c.1407A>C p.K469N | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52885548; called by muse, mutect2, varscan2
- PXDNL | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 179/520 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs200513898; called by muse, mutect2, varscan2
- RADIL | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 141/695 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as rs777596627, COSV68202496; called by muse, mutect2, varscan2
- RYR1 | c.11608G>A p.G3870R | Missense Mutation (SNP) | VAF 137/428 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs1306190316, COSV62100309; called by muse, varscan2
- SARM1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 83/833 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs1322636333; called by muse, mutect2
- SCN2A | c.5558A>T p.H1853L | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM145526; called by muse, mutect2, varscan2
- SPANXD | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 140/648 reads (22%) | catalogued as COSV65152248, COSV65152621; called by muse, mutect2, varscan2
- SSR4 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 113/595 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs142189119, COSV51245956; called by muse, mutect2, varscan2
- TMC3 | c.2776C>T p.R926* | Nonsense Mutation (SNP) | VAF 47/395 reads (12%) | catalogued as rs746059195, COSV63922496; called by muse, mutect2, varscan2
- TOPAZ1 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 118/485 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs1559520819, COSV59073182; called by muse, mutect2, varscan2
- TPR | c.2329G>A p.A777T | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.487); catalogued as rs766353558, COSV66603444; called by muse, mutect2
- TRMT61B | c.556dup p.A186Gfs*22 | Frame Shift Ins (INS) | VAF 100/406 reads (25%) | catalogued as rs746516437; called by mutect2, pindel, varscan2
- TTC7B | c.1468C>T p.R490* | Nonsense Mutation (SNP) | VAF 24/300 reads (8%) | catalogued as COSV60632849; called by muse, mutect2
- TTF1 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs962328231; called by muse, mutect2
- UNC5B | c.1639G>A p.G547S | Missense Mutation (SNP) | VAF 106/453 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs776460633; called by muse, mutect2, varscan2
- WDFY1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1419541352, COSV51792076; called by muse, mutect2
- WDFY4 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs371151010; called by muse, mutect2, varscan2
- ZNF665 | c.1616G>T p.G539V (on ENST00000600412; = p.G604V on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568651484, COSV101128234; called by muse, mutect2
- ACAN | c.7292G>A p.G2431E (on ENST00000560601 / NM_001369268.1; = p.G2355E on NM_001135.3) | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ADAMTS7 | c.2765C>A p.P922H | Missense Mutation (SNP) | VAF 149/517 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.4759G>A p.E1587K | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANKRD50 | c.3849del p.A1286Rfs*12 | Frame Shift Del (DEL) | VAF 51/296 reads (17%) | called by mutect2, pindel, varscan2
- AP2A1 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEST3 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 20/359 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- BX276092.9 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP135 | c.3120C>A p.N1040K | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CFAP161 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CFAP70 | c.2459C>A p.A820D | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHD5 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 49/399 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CHST7 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 194/916 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DKK2 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DLGAP2 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 59/456 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSG1 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- EXOC5 | c.2107C>T p.L703F | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FOLR3 | c.365A>G p.Q122R | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- GAK | c.1974+1G>A p.X658_splice | Splice Site (SNP) | VAF 62/341 reads (18%) | called by muse, mutect2, varscan2
- GBP5 | c.1656_1657insCA p.A553Qfs*? | Frame Shift Ins (INS) | VAF 36/244 reads (15%) | called by mutect2, pindel, varscan2
- GK2 | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- HIVEP2 | c.2247C>A p.N749K | Missense Mutation (SNP) | VAF 22/596 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2
- HRNR | c.963C>G p.S321R | Missense Mutation (SNP) | VAF 116/409 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF1 | c.3688C>A p.L1230I | Missense Mutation (SNP) | VAF 101/454 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IL24 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ILKAP | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- JMJD1C | c.5468C>G p.A1823G | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KANSL1L | c.597A>T p.K199N | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC37A3 | c.4544C>A p.A1515D | Missense Mutation (SNP) | VAF 198/644 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAGEB6B | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.325); called by muse, mutect2
- MAGIX | c.508G>T p.V170F | Missense Mutation (SNP) | VAF 53/559 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2
- MAP3K19 | c.2436A>T p.E812D | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- MARCO | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MDM2 | c.1144del p.E382Rfs*36 | Frame Shift Del (DEL) | VAF 45/198 reads (23%) | called by mutect2, pindel, varscan2
- NETO1 | c.605G>C p.C202S | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSMCE4A | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 205/841 reads (24%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NYX | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 194/906 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, varscan2
- OR4A8 | c.524T>C p.F175S | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- PCDH17 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 67/577 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- PDHA2 | c.1137T>A p.N379K | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PLS3 | c.501-1G>T p.X167_splice | Splice Site (SNP) | VAF 38/180 reads (21%) | called by muse, varscan2
- PPCS | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 103/630 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- PREX1 | c.1115G>T p.C372F | Missense Mutation (SNP) | VAF 189/593 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM27 | c.2789A>G p.Q930R | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RECQL4 | c.2335G>C p.D779H | Missense Mutation (SNP) | VAF 115/900 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- RFC1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SCMH1 | c.733C>T p.P245S (on ENST00000326197 / NM_001031694.2; = p.P198S on NM_012236.4) | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SHARPIN | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 44/555 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- SPSB4 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 28/670 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.616); called by muse, mutect2
- SS18L1 | c.459C>A p.S153R | Missense Mutation (SNP) | VAF 140/871 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); called by muse, varscan2
- TRIML1 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- UBR4 | c.9332G>A p.S3111N | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UTP14A | c.1359C>A p.S453R | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- WDR49 | c.308C>G p.S103C (on ENST00000308378 / NM_001366158.1; = p.S444C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/339 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XYLT2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 44/542 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2
- ZP2 | c.8G>T p.C3F | Missense Mutation (SNP) | VAF 49/407 reads (12%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZSWIM8 | c.2962G>A p.D988N (on ENST00000605216 / NM_001242487.2; = p.D993N on NM_015037.3) | Missense Mutation (SNP) | VAF 33/402 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2
- ZXDA | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 69/885 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADORA1 | c.471A>T p.A157= | Silent (SNP) | VAF 70/507 reads (14%) | called by muse, mutect2, varscan2
- AICDA | c.573C>T p.D191= | Silent (SNP) | VAF 29/294 reads (10%) | catalogued as rs369407243; called by muse, mutect2
- ANKRD24 | c.2988C>T p.S996= | Silent (SNP) | VAF 39/354 reads (11%) | catalogued as rs1193578267; called by muse, mutect2, varscan2
- ARHGAP22 | c.1062G>T p.P354= | Silent (SNP) | VAF 136/683 reads (20%) | catalogued as COSV99984084; called by muse, mutect2, varscan2
- ARHGEF33 | c.1833G>A p.A611= | Silent (SNP) | VAF 121/709 reads (17%) | catalogued as rs1340270478; called by muse, mutect2, varscan2
- AZGP1 | c.393C>T p.S131= | Silent (SNP) | VAF 102/419 reads (24%) | catalogued as rs777569319, COSV52796934; called by muse, mutect2, varscan2
- C9orf43 | c.1227C>T p.D409= | Silent (SNP) | VAF 56/326 reads (17%) | catalogued as rs200133500, COSV55913276; called by muse, mutect2, varscan2
- CACNG3 | c.339G>A p.T113= | Silent (SNP) | VAF 161/456 reads (35%) | catalogued as rs773149814, COSV50089370; called by muse, varscan2
- CACNG6 | c.105C>T p.R35= | Silent (SNP) | VAF 103/694 reads (15%) | catalogued as rs1396852422; called by muse, mutect2, varscan2
- CCDC65 | c.1308G>A p.L436= | Silent (SNP) | VAF 60/463 reads (13%) | catalogued as rs765852026; called by muse, mutect2, varscan2
- CLDN11 | c.432C>T p.C144= | Silent (SNP) | VAF 88/396 reads (22%) | catalogued as rs531634544, COSV50355545; called by muse, mutect2, varscan2
- CRB1 | c.4026C>T p.S1342= | Silent (SNP) | VAF 41/230 reads (18%) | catalogued as rs142057392; called by muse, mutect2, varscan2
- CRTAC1 | c.1985G>A p.*662= | Silent (SNP) | VAF 58/241 reads (24%) | called by muse, mutect2, varscan2
- CTSG | c.225C>T p.G75= | Silent (SNP) | VAF 37/277 reads (13%) | catalogued as rs143803246, COSV99361379; called by muse, mutect2, varscan2
- CUX2 | c.2151G>A p.A717= | Silent (SNP) | VAF 197/704 reads (28%) | catalogued as rs770133219, COSV55628460; called by muse, mutect2, varscan2
- DNAH5 | c.3942C>A p.G1314= | Silent (SNP) | VAF 80/415 reads (19%) | catalogued as COSV54227337; called by muse, mutect2, varscan2
- ESR1 | c.775C>A p.R259= | Silent (SNP) | VAF 36/400 reads (9%) | catalogued as CM016135; called by muse, mutect2
- FAM110B | c.531C>T p.G177= | Silent (SNP) | VAF 193/511 reads (38%) | catalogued as rs1449919905, COSV64067199; called by muse, mutect2, varscan2
- FAM178B | c.555G>A p.A185= | Silent (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- ITLN2 | c.69G>T p.G23= | Silent (SNP) | VAF 77/291 reads (26%) | called by muse, mutect2, varscan2
- KMT2D | c.2367C>T p.S789= | Silent (SNP) | VAF 71/571 reads (12%) | called by muse, mutect2, varscan2
- KRT17 | c.72G>A p.S24= | Silent (SNP) | VAF 146/554 reads (26%) | catalogued as rs536792008, COSV60860541; called by muse, mutect2, varscan2
- MADD | c.1887C>T p.D629= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs1394772264; called by muse, varscan2
- MAGEC3 | c.561G>A p.K187= | Silent (SNP) | VAF 54/468 reads (12%) | catalogued as rs955033126, COSV53577347; called by muse, mutect2, varscan2
- METTL21C | c.189C>T p.Y63= | Silent (SNP) | VAF 74/489 reads (15%) | catalogued as rs140891650; called by muse, mutect2, varscan2
- MICALL1 | c.2220C>T p.S740= | Silent (SNP) | VAF 54/399 reads (14%) | catalogued as rs144941788; called by muse, mutect2, varscan2
- MITF | c.1089C>T p.R363= (on ENST00000448226 / NM_006722.3; = p.R263= on NM_000248.4) | Silent (SNP) | VAF 108/513 reads (21%) | catalogued as rs576634776, COSV58831871; called by muse, mutect2, varscan2
- NEDD4L | c.861C>T p.L287= | Silent (SNP) | VAF 85/301 reads (28%) | catalogued as rs745685509; called by muse, mutect2, varscan2
- NEMF | c.2506T>C p.L836= | Silent (SNP) | VAF 36/164 reads (22%) | called by muse, mutect2, varscan2
- NFIC | c.12C>T p.S4= | Silent (SNP) | VAF 87/544 reads (16%) | catalogued as rs533262491; called by muse, mutect2, varscan2
- NOTCH3 | c.1866C>T p.D622= | Silent (SNP) | VAF 107/382 reads (28%) | catalogued as rs777959915, COSV54627926; called by muse, mutect2, varscan2
- OR4C13 | c.567T>C p.N189= | Silent (SNP) | VAF 88/392 reads (22%) | called by muse, mutect2, varscan2
- OR52K1 | c.324C>T p.S108= | Silent (SNP) | VAF 104/449 reads (23%) | catalogued as rs757354444; called by muse, mutect2, varscan2
- OR5D16 | c.159T>A p.I53= | Silent (SNP) | VAF 16/411 reads (4%) | called by muse, mutect2
- PCDHA10 | c.1359G>A p.A453= | Silent (SNP) | VAF 341/653 reads (52%) | catalogued as rs372428918, COSV56494213; called by muse, mutect2, varscan2
- PEX7 | c.273G>A p.S91= | Silent (SNP) | VAF 45/515 reads (9%) | catalogued as rs532273900; called by muse, mutect2
- PKHD1 | c.9348G>A p.L3116= | Silent (SNP) | VAF 63/461 reads (14%) | catalogued as rs769921100, CD054975, COSV61859218; called by muse, mutect2, varscan2
- PLEC | c.4482G>A p.E1494= (on ENST00000322810 / NM_201380.4; = p.E1384= on NM_000445.5) | Silent (SNP) | VAF 87/600 reads (15%) | called by muse, mutect2, varscan2
- PLXNB2 | c.4419A>T p.G1473= | Silent (SNP) | VAF 75/469 reads (16%) | called by muse, mutect2, varscan2
- RC3H2 | c.228C>T p.A76= | Silent (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2, varscan2
- RSPH10B2 | c.1698C>T p.P566= | Silent (SNP) | VAF 49/346 reads (14%) | called by muse, mutect2
- SLC6A2 | c.270C>T p.G90= | Silent (SNP) | VAF 28/299 reads (9%) | catalogued as rs1286710340, COSV54914770; called by muse, mutect2
- TGIF2LX | c.567G>A p.P189= | Silent (SNP) | VAF 106/579 reads (18%) | catalogued as rs34232559, COSV99383208; called by muse, mutect2
- TSHZ3 | c.810C>T p.D270= | Silent (SNP) | VAF 92/380 reads (24%) | catalogued as rs775613015, COSV53666834; called by muse, varscan2
- UNK | c.819G>A p.E273= | Silent (SNP) | VAF 18/380 reads (5%) | called by muse, mutect2
- WDR77 | c.21C>G p.P7= | Silent (SNP) | VAF 80/277 reads (29%) | catalogued as rs761289527; called by muse, mutect2, varscan2
- WNT7B | c.348G>A p.A116= | Silent (SNP) | VAF 151/504 reads (30%) | catalogued as rs754224066; called by muse, mutect2, varscan2
- ZDHHC14 | c.1332G>A p.A444= | Silent (SNP) | VAF 70/830 reads (8%) | catalogued as rs369643267; called by muse, mutect2
- ZNF423 | c.3843G>A p.E1281= (on ENST00000563137 / NM_001379286.1; = p.E1273= on NM_015069.4) | Silent (SNP) | VAF 13/336 reads (4%) | catalogued as rs1212019450; called by muse, mutect2
- REXO1L1P | n.814C>T | RNA (SNP) | VAF 28/844 reads (3%) | called by muse, mutect2
